Somatic mutation profile of tumor specimen TCGA-2G-AALF-01A (aliquot TCGA-2G-AALF-01A-11D-A42Y-10) from TCGA case TCGA-2G-AALF, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a2fb939-c801-40d1-8770-50494cf9836c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AALF-10A (Blood Derived Normal), aliquot TCGA-2G-AALF-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3066fd2c-81c4-441f-aac3-4d9a70fb131e

The open-access MAF lists 22 somatic variants for this specimen: 12 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, 5'UTR 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD5 | c.1973A>C p.K658T | Missense Mutation (SNP) | VAF 84/406 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1467160326; called by muse, mutect2, varscan2
- C10orf67 | c.605C>A p.T202K (on ENST00000636213 / NM_001365862.2; = p.T170K on NM_001351306.2) | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs554333696; called by muse, mutect2
- MC1R | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs760458744, COSV59624972; called by muse, mutect2, varscan2
- NEB | c.17080G>A p.V5694I | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as rs1396168176; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PUS7 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62675791; called by muse, mutect2, varscan2
- ZDHHC11B | c.948G>C p.K316N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs1461215919; called by muse, mutect2
- GPANK1 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LAMB3 | c.1608_1609del p.C536* | Nonsense Mutation (DEL) | VAF 32/114 reads (28%) | called by pindel, varscan2
- OSCP1 | c.745T>A p.Y249N (on ENST00000356637 / NM_001330493.1; = p.Y239N on NM_145047.5) | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- POR | c.1575C>G p.F525L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TECTA | c.4565A>G p.D1522G | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TNRC6C | c.3224A>G p.N1075S | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ITGB8 | c.318T>G p.V106= | Silent (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- KLF13 | c.546G>C p.S182= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- KRTAP4-6 | c.606C>T p.S202= | Silent (SNP) | VAF 87/233 reads (37%) | called by muse, mutect2, varscan2
- LRP1 | c.11598G>A p.E3866= | Silent (SNP) | VAF 26/47 reads (55%) | called by muse, mutect2, varscan2
- LRRC46 | c.645G>A p.R215= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs1318540789; called by muse, mutect2, varscan2
- NLRP6 | c.1761C>T p.P587= | Silent (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- RPS6KA6 | c.1314T>C p.S438= | Silent (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2, varscan2
- APOC1 | c.-10C>T | 5'UTR (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- MIR29B2CHG | n.244G>T | RNA (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- PEMT | c.-4C>T | 5'UTR (SNP) | VAF 15/49 reads (31%) | catalogued as rs753726492, COSV99703339; called by muse, mutect2, varscan2
